Somatic mutation profile of tumor specimen TCGA-D3-A2JE-06A (aliquot TCGA-D3-A2JE-06A-11D-A372-08) from TCGA case TCGA-D3-A2JE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.0 years (27,744 days).
Specimen TCGA-D3-A2JE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 373211e9-42a7-4d19-8e48-019f04352c72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JE-10B (Blood Derived Normal), aliquot TCGA-D3-A2JE-10B-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/095b4d07-16e2-4e31-b63e-323818f48c3a

The open-access MAF lists 401 somatic variants for this specimen: 245 protein-altering or splice-affecting, 143 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 204, Silent 143, Nonsense Mutation 18, Frame Shift Del 6, Splice Region 6, Splice Site 6, Intron 4, RNA 4, Frame Shift Ins 3, In Frame Del 2, 3'UTR 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RORC | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774357869, CM158000, COSV100562072, COSV59094013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 50/77 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs142762485, COSV53196450; called by muse, mutect2, varscan2
- ABCA12 | c.1423G>A p.E475K (on ENST00000272895 / NM_173076.3; = p.E157K on NM_015657.3) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs374329275; called by muse, mutect2, varscan2
- ABCA3 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.027); catalogued as COSV100068993; called by muse, mutect2, varscan2
- ABCA4 | c.1526C>T p.T509I | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100933201; called by muse, mutect2, varscan2
- ABCF1 | c.64A>T p.S22C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.174); catalogued as COSV100400992; called by muse, mutect2
- AC134980.2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs772319712, COSV60909017; called by muse, mutect2, varscan2
- ACTRT2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); catalogued as rs977084051, COSV65759494; called by muse, mutect2, varscan2
- ACVR1C | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 88/143 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99694955; called by muse, mutect2, varscan2
- ADH1C | c.966C>T p.G322= | Splice Region (SNP) | VAF 52/123 reads (42%) | catalogued as rs1225012346, COSV101565180; called by muse, mutect2, varscan2
- ANKZF1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 74/115 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV99850813; called by muse, mutect2, varscan2
- APBB1 | c.1105-2A>G p.X369_splice | Splice Site (SNP) | VAF 37/82 reads (45%) | catalogued as COSV100194254; called by muse, mutect2, varscan2
- ARHGAP28 | c.1261C>T p.R421* (on ENST00000383472 / NM_001366230.1; = p.R262* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 61/167 reads (37%) | catalogued as rs781727091, COSV51633725; called by muse, mutect2, varscan2
- ATP10D | c.4169C>T p.S1390F | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs112565536, COSV56689990; called by muse, mutect2, varscan2
- ATRX | c.5622A>C p.Q1874H | Missense Mutation (SNP) | VAF 100/544 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100971274; called by muse, mutect2, varscan2
- AUTS2 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV100719219; called by muse, mutect2, varscan2
- BABAM2 | c.1089-1G>A p.X363_splice | Splice Site (SNP) | VAF 171/203 reads (84%) | catalogued as COSV100568582; called by muse, mutect2, varscan2
- BEND2 | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 222/353 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV101192172; called by muse, mutect2, varscan2
- BTBD11 | c.3113G>A p.G1038E (on ENST00000280758 / NM_001018072.2; = p.G575E on NM_001017523.2) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.153); catalogued as COSV99776660; called by muse, mutect2, varscan2
- C3AR1 | c.53G>A p.W18* | Nonsense Mutation (SNP) | VAF 49/99 reads (49%) | catalogued as COSV99368855; called by muse, mutect2, varscan2
- C6 | c.1346G>A p.S449N | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.606); catalogued as COSV99667609; called by muse, mutect2, varscan2
- CA2 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 234/493 reads (47%) | catalogued as COSV99570230; called by muse, mutect2, varscan2
- CACNA2D2 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99818206; called by muse, mutect2, varscan2
- CARMIL2 | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100576212; called by muse, mutect2, varscan2
- CCDC73 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as rs267602856, COSV58795674; called by muse, mutect2, varscan2
- CDC73 | c.1223G>T p.R408I | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV100813950; called by muse, mutect2, varscan2
- CDH6 | c.1631-1G>A p.X544_splice | Splice Site (SNP) | VAF 37/122 reads (30%) | catalogued as COSV99420438; called by muse, mutect2, varscan2
- CDKL5 | c.2374A>G p.T792A | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1253960118, COSV101184433; called by muse, mutect2, varscan2
- CDON | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV99701822; called by muse, mutect2, varscan2
- CEP43 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 152/176 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100835717; called by muse, mutect2, varscan2
- CLCN4 | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101073978; called by muse, mutect2, varscan2
- CMSS1 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs772691746, COSV101375616; called by muse, mutect2, varscan2
- COL11A2 | c.3172C>T p.P1058S (on ENST00000341947 / NM_080680.3; = p.P951S on NM_080679.2) | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100554410; called by muse, mutect2, varscan2
- COL7A1 | c.5830C>T p.R1944W | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs527416146, COSV60406432; called by muse, mutect2, varscan2
- CRB2 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs865783695, COSV100749720; called by muse, mutect2, varscan2
- CXADR | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV99515079; called by muse, mutect2, varscan2
- CYP26A1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV56419896; called by muse, mutect2, varscan2
- CYP4F11 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs927033952, COSV99931043; called by muse, mutect2, varscan2
- CYP8B1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV100296253; called by muse, mutect2, varscan2
- DAB1 | c.1246C>T p.P416S (on ENST00000371231; = p.P383S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV64690305; called by muse, mutect2, varscan2
- DCAF12L1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 90/154 reads (58%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as COSV64421706; called by muse, mutect2, varscan2
- DGKH | c.3208C>T p.P1070S | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866644179, COSV54942556; called by muse, mutect2, varscan2
- DNAH10 | c.6974G>A p.W2325* (on ENST00000409039; = p.W2264* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV101292502; called by muse, varscan2
- DNAH11 | c.5471C>T p.P1824L | Missense Mutation (SNP) | VAF 139/375 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV100180303; called by muse, mutect2, varscan2
- DNAH3 | c.10718G>A p.G3573E | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1183233718, COSV99769841; called by muse, mutect2, varscan2
- DNAJC13 | c.3941+1G>C p.X1314_splice | Splice Site (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99607863; called by muse, mutect2, varscan2
- DSG1 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 135/213 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs267605156, COSV99936421; called by muse, mutect2, varscan2
- ENPP3 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781156968, COSV62952931; called by muse, mutect2, varscan2
- FAM169A | c.31T>A p.C11S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.577); catalogued as COSV100998396; called by muse, mutect2, varscan2
- FBXO30 | c.1428G>C p.E476D | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746247911, COSV99395369; called by muse, mutect2, varscan2
- FERMT3 | c.1682+1G>A p.X561_splice (on ENST00000279227 / NM_178443.3; = p.X557_splice on NM_031471.6 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99656750; called by muse, mutect2, varscan2
- FLG | c.8468G>A p.G2823E | Missense Mutation (SNP) | VAF 168/1267 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV64244380; called by muse, mutect2, varscan2
- FLRT3 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 116/201 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV99440381; called by muse, mutect2, varscan2
- FLT3 | c.2822C>T p.S941L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs548609046, COSV54056383; called by muse, mutect2, varscan2
- FNDC1 | c.4771G>A p.E1591K | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.19); PolyPhen benign (0.242); catalogued as rs1237613980, COSV51944247; called by muse, mutect2, varscan2
- FRAS1 | c.7362G>A p.M2454I | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as rs1317933843, COSV99355019; called by muse, mutect2, varscan2
- FYB1 | c.2127T>A p.Y709* (on ENST00000351578 / NM_199335.5; = p.Y755* on NM_001465.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100686104; called by muse, mutect2, varscan2
- GABRB3 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1220761805, COSV54661057; called by muse, mutect2, varscan2
- GIMAP5 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 84/160 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.408); catalogued as rs1405733996, COSV100500289; called by muse, mutect2, varscan2
- GPC4 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 175/584 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63697091; called by muse, mutect2, varscan2
- GRIN3A | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV62454628, COSV62456793, COSV62456870; called by muse, mutect2, varscan2
- GSDMC | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as COSV99416355; called by muse, mutect2, varscan2
- GUCY2C | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 141/258 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV99663672; called by muse, mutect2, varscan2
- HDAC9 | c.2836G>A p.G946R | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101287015; called by muse, mutect2, varscan2
- HHIP | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1403317748, COSV99667697; called by muse, mutect2, varscan2
- HLA-DMA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100877682; called by muse, mutect2, varscan2
- HYDIN | c.11472G>A p.E3824= | Splice Region (SNP) | VAF 8/40 reads (20%) | catalogued as rs1462100886, COSV101125190; called by muse, mutect2, varscan2
- IGFBPL1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1449840428, COSV100890749, COSV66618092; called by muse, mutect2, varscan2
- IL12B | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); catalogued as COSV51455942; called by muse, mutect2, varscan2
- INTS11 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300023880, COSV100028591; called by muse, mutect2, varscan2
- ITGB8 | c.1913G>A p.W638* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99752117; called by muse, mutect2, varscan2
- KCNH1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99660776; called by muse, mutect2, varscan2
- KLHL13 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV53247863; called by muse, mutect2, varscan2
- KLHL34 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs758975840, COSV101069980; called by muse, varscan2
- KMT2C | c.3709C>T p.R1237* | Nonsense Mutation (SNP) | VAF 49/119 reads (41%) | catalogued as rs938655561, COSV51498512; called by muse, mutect2, varscan2
- L1TD1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs1266668702, COSV63134287; called by muse, mutect2
- LAD1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1209895242, COSV66213082; called by muse, mutect2, varscan2
- LAS1L | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV100408660; called by muse, mutect2, varscan2
- LCE1F | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); catalogued as rs116630978, COSV57668863; called by muse, varscan2
- LGALS9C | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 106/134 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60195380; called by muse, mutect2, varscan2
- LRP1B | c.13631C>T p.S4544F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs1474743399, COSV101259563; called by muse, mutect2, varscan2
- LRP1B | c.2261C>T p.T754I | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101262462, COSV67228787; called by muse, mutect2, varscan2
- LRP2 | c.4666G>A p.G1556R | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789824; called by muse, mutect2, varscan2
- LRRTM4 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs766753532, COSV69139955; called by muse, mutect2, varscan2
- LVRN | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 99/166 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs369575731; called by muse, mutect2, varscan2
- LYVE1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 143/322 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99811157; called by muse, mutect2, varscan2
- LZTS3 | c.1952C>T p.P651L (on ENST00000329152; = p.P605L on NM_001282533.2) | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1395107584, COSV99418461; called by muse, mutect2, varscan2
- MAP1B | c.3275G>A p.G1092E | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99702816; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>C p.G1366R | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- MAP9 | c.1490dup p.N497Kfs*6 | Frame Shift Ins (INS) | VAF 18/99 reads (18%) | catalogued as rs778055136; called by mutect2, varscan2
- MECOM | c.1832G>A p.G611E (on ENST00000468789 / NM_001105078.4; = p.G799E on NM_004991.4) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599684, COSV52962370; called by muse, mutect2, varscan2
- MED12 | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100379460; called by muse, mutect2, varscan2
- MEGF10 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99175403; called by muse, mutect2, varscan2
- MEPCE | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1198018248, COSV99440208; called by muse, mutect2, varscan2
- MMD2 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as COSV101287102; called by muse, mutect2, varscan2
- MORC1 | c.2753A>T p.K918M | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99227358; called by muse, mutect2, varscan2
- MS4A1 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1173252862, COSV100619413; called by muse, mutect2, varscan2
- MUC5B | c.14486C>T p.T4829I | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.192); catalogued as COSV101500649; called by muse, mutect2, varscan2
- MVP | c.2618C>T p.S873F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs111546502, COSV62422216; called by muse, mutect2, varscan2
- MYH6 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100676374, COSV100676900; called by muse, mutect2, varscan2
- MYL7 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99790090; called by muse, mutect2, varscan2
- MYO16 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 126/207 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51814460, COSV51816840; called by muse, mutect2, varscan2
- NAB1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV61608118; called by muse, mutect2, varscan2
- NAMPT | c.450T>C p.T150= | Splice Region (SNP) | VAF 24/112 reads (21%) | catalogued as rs745474987, COSV99748211; called by muse, mutect2, varscan2
- NEK5 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs267603847, COSV62879653; called by muse, mutect2, varscan2
- NEPRO | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1323381163, COSV99868485; called by muse, mutect2
- NEXMIF | c.3409C>T p.Q1137* | Nonsense Mutation (SNP) | VAF 75/176 reads (43%) | catalogued as COSV50126694; called by muse, mutect2, varscan2
- NLRP10 | c.242T>G p.M81R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV100149908; called by muse, mutect2, varscan2
- NLRP14 | c.2902G>A p.D968N | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV55064813, COSV55068685; called by muse, mutect2, varscan2
- NLRP8 | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 105/181 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs933438408, COSV52589152, COSV99405791; called by muse, mutect2, varscan2
- NOA1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV99950651; called by muse, mutect2, varscan2
- NOL4 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99307954; called by muse, mutect2
- NPAP1 | c.680C>G p.A227G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV100275953, COSV61509798; called by muse, mutect2, varscan2
- NPAP1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1215164282, COSV100275955; called by muse, mutect2, varscan2
- NR5A2 | c.430C>T p.Q144* (on ENST00000367362 / NM_205860.3; = p.Q98* on NM_003822.5) | Nonsense Mutation (SNP) | VAF 29/98 reads (30%) | catalogued as COSV99371527; called by muse, mutect2, varscan2
- NUAK2 | c.690G>A p.E230= | Splice Region (SNP) | VAF 51/95 reads (54%) | catalogued as COSV100904134; called by muse, mutect2, varscan2
- OR1S2 | c.38A>C p.N13T | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV100224341; called by muse, mutect2, varscan2
- OR2M5 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 125/696 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV63546865; called by muse, mutect2, varscan2
- OR4C15 | c.658C>T p.P220S (on ENST00000314644; = p.P166S on NM_001001920.2) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.273); catalogued as COSV58952983; called by muse, mutect2, varscan2
- OR4C15 | c.1010C>T p.P337L (on ENST00000314644; = p.P283L on NM_001001920.2) | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs774055903, COSV58953325, COSV58954238, COSV58955502; called by muse, mutect2, varscan2
- OR51A7 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100834733; called by muse, mutect2, varscan2
- OR52W1 | c.483_485del p.V162del | In Frame Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs1006875122; called by pindel, varscan2
- OR5L1 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs139907396, COSV61733292; called by muse, mutect2, varscan2
- OR8B4 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV100635864; called by muse, mutect2, varscan2
- OSGEP | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.074); catalogued as COSV99248161; called by muse, mutect2, varscan2
- OTOGL | c.3262G>A p.D1088N (on ENST00000547103; = p.D1079N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1162999940, COSV101509474; called by muse, mutect2, varscan2
- OTULIN | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | catalogued as COSV99419986; called by muse, mutect2, varscan2
- P2RY8 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV101184157; called by muse, mutect2, varscan2
- PAH | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1402168594, CM1513415, COSV61014279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPPA | c.1697A>T p.H566L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100075024; called by muse, mutect2, varscan2
- PCDHA11 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs781996593, COSV56502100; called by muse, mutect2, varscan2
- PCDHA11 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs781950776, COSV56559987; called by muse, mutect2, varscan2
- PCDHA13 | c.2359G>A p.G787S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs140550923, COSV99169076; called by muse, mutect2, varscan2
- PCDHB2 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.258); catalogued as COSV50564910, COSV50573455; called by muse, varscan2
- PCLO | c.4586G>A p.R1529Q | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs201456948, COSV61629977, COSV61641483; called by muse, mutect2, varscan2
- PGK2 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755451283, COSV59162813; called by muse, mutect2, varscan2
- PJA1 | c.79A>G p.R27G | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100824784; called by muse, mutect2, varscan2
- PKD2 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV52941587; called by muse, mutect2, varscan2
- PKHD1L1 | c.8297G>A p.R2766K | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV65742694; called by muse, mutect2, varscan2
- PLEKHM1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV101378844; called by muse, mutect2, varscan2
- PLG | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 105/131 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1261821465, COSV51987988; called by muse, mutect2, varscan2
- PLK1 | c.1600T>A p.F534I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99892166; called by muse, mutect2, varscan2
- PPP1R1B | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV99566333; called by muse, mutect2, varscan2
- PRKCB | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100335008; called by muse, mutect2, varscan2
- PRPS2 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1272916093, COSV101028396; called by muse, mutect2
- PRSS16 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as COSV100041928; called by muse, mutect2, varscan2
- PSG5 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 118/214 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV61654021; called by muse, mutect2, varscan2
- PSG9 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 134/384 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99392508; called by muse, mutect2, varscan2
- PTPN12 | c.1697_1698del p.V566Efs*11 | Frame Shift Del (DEL) | VAF 28/208 reads (13%) | catalogued as rs1229004721; called by pindel, varscan2
- QRICH2 | c.3640C>T p.P1214S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1395993472, COSV99429581; called by muse, mutect2, varscan2
- RAI1 | c.4883C>T p.S1628F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.28); catalogued as rs773872471, COSV99884782; called by muse, mutect2, varscan2
- RASGRF1 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101174701; called by muse, mutect2, varscan2
- RB1 | c.865A>T p.K289* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as rs1160807049, CM143225, COSV57301073; called by muse, mutect2, varscan2
- RB1 | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs1231557654, CM030517, COSV57307568; called by muse, mutect2, varscan2
- REM2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs779523287, COSV99944746; called by muse, mutect2, varscan2
- RESF1 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57023112; called by muse, mutect2, varscan2
- REV3L | c.7496G>A p.R2499Q | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as rs779309475, COSV62615464; called by muse, mutect2, varscan2
- RIMS2 | c.4207C>T p.L1403= (on ENST00000666250 / NM_001348490.2; = p.L974= on NM_014677.5 and 7 other RefSeq transcripts) | Splice Region (SNP) | VAF 71/173 reads (41%) | catalogued as COSV51662796; called by muse, mutect2, varscan2
- RNF113A | c.967A>T p.T323S | Missense Mutation (SNP) | VAF 262/458 reads (57%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101007094; called by muse, mutect2
- RTEL1 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1197705603, COSV100542731; called by muse, mutect2, varscan2
- RYR3 | c.10669C>T p.L3557F (on ENST00000389232; = p.L3558F on NM_001036.6) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV101213875; called by muse, mutect2, varscan2
- SALL3 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs865980784, COSV101610041; called by muse, mutect2, varscan2
- SBF1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs764224576, COSV100817975; called by muse, mutect2, varscan2
- SCML2 | c.1425C>G p.H475Q | Missense Mutation (SNP) | VAF 39/512 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV99319404; called by muse, mutect2
- SCN11A | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778518459, COSV56568512; called by muse, mutect2, varscan2
- SCN5A | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100028473; called by muse, mutect2
- SCRN2 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99274279; called by muse, mutect2, varscan2
- SERPINA4 | c.910T>A p.L304M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV100097404; called by muse, mutect2, varscan2
- SETD2 | c.4942G>T p.V1648F | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100339778; called by muse, mutect2, varscan2
- SETD2 | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as rs778145277, COSV100339779; called by muse, mutect2, varscan2
- SF3A1 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99305652; called by muse, mutect2, varscan2
- SF3A1 | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99305655; called by muse, mutect2, varscan2
- SI | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139012673, COSV100013402, COSV52268042; called by muse, mutect2, varscan2
- SIGLEC6 | c.1014G>A p.W338* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs779362570, COSV58436051; called by muse, mutect2, varscan2
- SIRPG | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs370463374, COSV99403920; called by muse, mutect2, varscan2
- SLC2A4 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs146787418, COSV99142768; called by muse, mutect2, varscan2
- SLC6A16 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as rs758366362, COSV60027406; called by muse, mutect2, varscan2
- SLC9A7 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.81); PolyPhen benign (0.104); catalogued as COSV100092624; called by muse, mutect2, varscan2
- SORL1 | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769806986, COSV52762752; called by muse, mutect2, varscan2
- SPATA31A1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 128/523 reads (24%) | catalogued as rs1388438641; called by muse, varscan2
- SPHKAP | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60884723; called by muse, mutect2, varscan2
- SPHKAP | c.3411G>A p.M1137I | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60892555; called by muse, mutect2, varscan2
- ST6GAL2 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as rs1376433010, COSV100868231; called by muse, mutect2, varscan2
- STARD8 | c.2182C>T p.H728Y | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99367417; called by muse, mutect2, varscan2
- STAT3 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.895); catalogued as COSV52883309; called by muse, mutect2, varscan2
- STK36 | c.3709C>T p.L1237F | Missense Mutation (SNP) | VAF 85/108 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99831829; called by muse, mutect2, varscan2
- STXBP5L | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56524952; called by muse, mutect2, varscan2
- SYNCRIP | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 105/129 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0.249); catalogued as rs1455212560, COSV62289507; called by muse, mutect2, varscan2
- SYNDIG1 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100965396; called by muse, mutect2
- SYT1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54076001; called by muse, mutect2, varscan2
- TAS2R41 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601368, COSV68765074; called by muse, mutect2, varscan2
- TBC1D8 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558638484, COSV100964495, COSV65215365; called by muse, mutect2
- TCP11L2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.431); catalogued as COSV54429041; called by muse, mutect2, varscan2
- TECTA | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99881159; called by muse, mutect2, varscan2
- TENM3 | c.5341C>T p.R1781* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs773188257, COSV101305390; called by muse, mutect2, varscan2
- TLL1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1274354943, COSV50314840; called by muse, mutect2, varscan2
- TLL1 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99286792, COSV99288641; called by muse, mutect2, varscan2
- TMED8 | c.954C>G p.Y318* | Nonsense Mutation (SNP) | VAF 72/115 reads (63%) | catalogued as COSV99375169; called by muse, mutect2, varscan2
- TMEM168 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs755373271, COSV57181281; called by muse, mutect2, varscan2
- TMEM176A | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99133940; called by muse, mutect2, varscan2
- TMEM200A | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 77/95 reads (81%) | SIFT tolerated (0.72); PolyPhen benign (0.092); catalogued as COSV51650951; called by muse, mutect2, varscan2
- TNC | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100406122; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2, varscan2
- TRIM50 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as COSV100297278; called by muse, mutect2, varscan2
- TRPM3 | c.443G>A p.G148E (on ENST00000357533 / NM_001366142.2; = p.G117E on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV100625384; called by muse, mutect2, varscan2
- TSPEAR | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1555915539, COSV100555032; called by muse, mutect2, varscan2
- TTBK2 | c.3173C>T p.S1058L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99142257; called by muse, mutect2, varscan2
- TTC7B | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as rs763103415, COSV100128404; called by muse, mutect2, varscan2
- TTN | c.59110G>A p.E19704K (on ENST00000591111; = p.E12280K on NM_003319.4) | Missense Mutation (SNP) | VAF 121/173 reads (70%) | PolyPhen benign (0.05); catalogued as rs776495338, COSV60242480; called by muse, mutect2, varscan2
- TTN | c.34263A>C p.K11421N (on ENST00000591111; = p.K10494N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | PolyPhen benign (0.311); catalogued as COSV100625426; called by muse, mutect2
- TTN | c.17640A>G p.E5880= (on ENST00000591111; = p.E4953= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 32/123 reads (26%) | catalogued as rs999871371, COSV100625427, COSV60050807; called by muse, mutect2, varscan2
- TTN | c.6069G>C p.K2023N (on ENST00000591111; = p.K1977N on NM_003319.4) | Missense Mutation (SNP) | VAF 45/235 reads (19%) | PolyPhen probably damaging (0.943); catalogued as COSV100625428, COSV60157958; called by muse, mutect2, varscan2
- TUBAL3 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100990556; called by muse, mutect2, varscan2
- UGT2B10 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | catalogued as COSV55319975; called by muse, mutect2, varscan2
- UGT2B28 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 127/153 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59431492; called by muse, mutect2, varscan2
- UNC119B | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100763503; called by muse, mutect2, varscan2
- USH1G | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as rs1291736274, COSV100140587; called by muse, mutect2, varscan2
- VAV1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 215/955 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1054377673, COSV100409395; called by muse, mutect2, varscan2
- VEGFC | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV54595809, COSV99710192; called by muse, mutect2, varscan2
- VSTM2A | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100173298; called by muse, mutect2, varscan2
- ZAN | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV61805735, COSV61809213; called by muse, mutect2, varscan2
- ZDBF2 | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV100985365; called by muse, mutect2, varscan2
- ZHX2 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 125/247 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs769413931, COSV100073733; called by muse, mutect2, varscan2
- ZIM2 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV55625605, COSV99690046; called by muse, mutect2, varscan2
- ZNF394 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100529936; called by muse, mutect2, varscan2
- ZNF430 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1338517810, COSV99841947; called by muse, mutect2, varscan2
- ZNF543 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs756690735, COSV100386898; called by muse, mutect2, varscan2
- ZNF568 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100451396, COSV61742881; called by muse, mutect2
- ZNF746 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100502550; called by muse, mutect2, varscan2
- ZNF780A | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 149/334 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61814960; called by muse, mutect2, varscan2
- ZNF804A | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as rs1474857214, COSV100169596, COSV99043240; called by muse, mutect2, varscan2
- ZNRF4 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs367699536, COSV55773425; called by muse, mutect2, varscan2
- CAND2 | c.1442-2_1456del p.X481_splice (on ENST00000456430 / NM_001162499.2; = p.X388_splice on NM_012298.3) | Splice Site (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- FANCB | c.824dup p.N275Kfs*33 | Frame Shift Ins (INS) | VAF 41/225 reads (18%) | called by mutect2, pindel, varscan2
- HMGCS2 | c.410dup p.S138Vfs*19 | Frame Shift Ins (INS) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- KRTAP5-2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LY75 | c.2024_2041del p.E675_L681delinsV | In Frame Del (DEL) | VAF 21/188 reads (11%) | called by mutect2, pindel, varscan2
- MS4A12 | c.737del p.P246Lfs*2 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- NUAK2 | c.61del p.R21Gfs*7 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- OR11H12 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- PAK5 | c.1195_1207del p.S399Pfs*75 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel, varscan2
- PTCH2 | c.3136_3152del p.S1046Rfs*5 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- TRGV3 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF22 | c.604del p.I202Sfs*3 | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | called by mutect2, pindel, varscan2
- ABCA2 | c.5199C>T p.V1733= (on ENST00000614293; = p.V1703= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/74 reads (55%) | catalogued as rs992321297, COSV99688260; called by muse, mutect2, varscan2
- ABCF1 | c.63G>T p.T21= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100400989; called by muse, mutect2
- ADAM19 | c.2307G>A p.T769= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs763134049, COSV57422622, COSV57428023; called by muse, mutect2, varscan2
- ADH6 | c.987C>T p.I329= | Silent (SNP) | VAF 64/150 reads (43%) | catalogued as COSV99422749; called by muse, mutect2, varscan2
- AHNAK2 | c.12360C>T p.S4120= | Silent (SNP) | VAF 274/505 reads (54%) | catalogued as COSV100318618, COSV60914268; called by muse, mutect2, varscan2
- AMOT | c.3198T>C p.T1066= (on ENST00000371959 / NM_001113490.1; = p.T657= on NM_133265.3) | Silent (SNP) | VAF 130/792 reads (16%) | catalogued as COSV100495169; called by muse, mutect2, varscan2
- ANK3 | c.7731G>A p.V2577= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as COSV55061134; called by muse, mutect2, varscan2
- AP002512.3 | c.1068G>A p.G356= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99688090; called by muse, mutect2, varscan2
- AP3S1 | c.189G>A p.L63= | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as COSV100372890; called by muse, mutect2
- ASB5 | c.159G>A p.R53= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV56670880, COSV99641545; called by muse, mutect2, varscan2
- ATXN1 | c.903C>T p.V301= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as rs1316191028, COSV99787402; called by muse, mutect2, varscan2
- BEND2 | c.1824G>A p.R608= | Silent (SNP) | VAF 223/355 reads (63%) | catalogued as COSV101192173; called by muse, mutect2, varscan2
- CAPSL | c.348C>T p.I116= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV68438405; called by muse, mutect2, varscan2
- CASP14 | c.384C>T p.I128= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV99693116; called by muse, mutect2, varscan2
- CASR | c.2382G>A p.E794= (on ENST00000490131; = p.E871= on NM_000388.4) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1553769147, COSV56140847; ClinVar: likely benign; called by muse, mutect2, varscan2
- CENPI | c.1047A>G p.Q349= | Silent (SNP) | VAF 184/371 reads (50%) | catalogued as COSV99515725; called by muse, mutect2, varscan2
- CHRNA10 | c.1290C>T p.F430= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV99167236; called by muse, mutect2, varscan2
- CHRNB3 | c.681C>T p.F227= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs1319324720, COSV99251407; called by muse, mutect2, varscan2
- COL5A3 | c.570G>A p.Q190= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs774543729, COSV53415601, COSV99319551; called by muse, mutect2, varscan2
- COL8A1 | c.1599G>A p.G533= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1427484282, COSV99658244; called by muse, mutect2, varscan2
- CP | c.2742G>A p.L914= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99224380; called by muse, mutect2, varscan2
- CREBBP | c.942C>T p.I314= | Silent (SNP) | VAF 79/196 reads (40%) | catalogued as COSV52126798; called by muse, mutect2, varscan2
- CRHR2 | c.729C>A p.A243= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV100530127; called by muse, mutect2, varscan2
- CTNNA3 | c.1893G>A p.E631= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV101051173, COSV65573425; called by muse, mutect2, varscan2
- CTU2 | c.729G>A p.Q243= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99966454; called by muse, mutect2, varscan2
- CUL9 | c.2427C>T p.I809= | Silent (SNP) | VAF 29/194 reads (15%) | catalogued as rs768871305, COSV99335867; called by muse, mutect2, varscan2
- DCAF12L1 | c.921G>A p.R307= | Silent (SNP) | VAF 89/152 reads (59%) | catalogued as COSV100948419; called by muse, mutect2, varscan2
- DHRS9 | c.24C>T p.L8= | Silent (SNP) | VAF 88/129 reads (68%) | catalogued as rs773264274, COSV100513650; called by muse, mutect2, varscan2
- DISP2 | c.852G>A p.K284= | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as COSV51117496; called by muse, mutect2, varscan2
- DLEC1 | c.789C>T p.F263= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs755377750, COSV57297689; called by muse, mutect2, varscan2
- DNAH17 | c.5994G>A p.R1998= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV101103178; called by muse, mutect2, varscan2
- DNAH5 | c.11706G>A p.K3902= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV54203346, COSV99452921; called by muse, mutect2, varscan2
- EPHA6 | c.2460G>A p.Q820= (on ENST00000389672 / NM_001080448.3; = p.Q212= on NM_173655.4) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV101065076; called by muse, mutect2, varscan2
- FAM47C | c.2802G>A p.V934= | Silent (SNP) | VAF 79/291 reads (27%) | catalogued as rs782235862, COSV100792899; called by muse, mutect2, varscan2
- FBN1 | c.7998C>T p.T2666= | Silent (SNP) | VAF 61/101 reads (60%) | catalogued as rs1374170310, COSV100354946; ClinVar: likely benign; called by muse, mutect2, varscan2
- FGF6 | c.612C>T p.F204= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57403697; called by muse, mutect2, varscan2
- FMO5 | c.594G>A p.G198= | Silent (SNP) | VAF 26/192 reads (14%) | catalogued as COSV99567339; called by muse, mutect2, varscan2
- FOLR2 | c.282C>T p.F94= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs200746182; called by muse, mutect2, varscan2
- GDPGP1 | c.1119G>A p.Q373= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV100292122, COSV61576103; called by muse, mutect2, varscan2
- GIMAP8 | c.1281G>A p.G427= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs867599282, COSV56229782; called by muse, mutect2
- GPR89B | c.39C>T p.S13= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100032592; called by muse, mutect2, varscan2
- GYG1 | c.258G>A p.K86= | Silent (SNP) | VAF 62/115 reads (54%) | catalogued as COSV99936930; called by muse, mutect2, varscan2
- HRH1 | c.469C>T p.L157= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs969847084, COSV101229098, COSV67954998; called by muse, mutect2, varscan2
- HSD17B6 | c.705G>A p.K235= | Silent (SNP) | VAF 93/164 reads (57%) | catalogued as COSV100444419; called by muse, mutect2, varscan2
- HTR1A | c.180C>T p.A60= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1041840819, COSV100109230; called by muse, mutect2, varscan2
- HTRA1 | c.1095G>A p.T365= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs752097769, COSV64563957; called by muse, mutect2, varscan2
- IGSF5 | c.156G>A p.K52= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101012015, COSV101012123; called by muse, mutect2, varscan2
- IKBKE | c.1743C>T p.F581= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV65623118; called by muse, mutect2, varscan2
- IL4R | c.174C>T p.L58= | Silent (SNP) | VAF 71/156 reads (46%) | catalogued as COSV50149514; called by muse, mutect2, varscan2
- KCNA2 | c.1020C>T p.I340= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as COSV100316088; called by muse, mutect2, varscan2
- KCNB2 | c.981C>T p.T327= | Silent (SNP) | VAF 122/210 reads (58%) | catalogued as COSV101578935; called by muse, mutect2, varscan2
- KIAA0753 | c.1269C>T p.F423= | Silent (SNP) | VAF 64/169 reads (38%) | catalogued as rs1308731501, COSV100810680; called by muse, mutect2, varscan2
- KIAA1217 | c.4749C>T p.A1583= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs745602761, COSV100287100; called by muse, mutect2, varscan2
- KIF3B | c.1474C>T p.L492= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as rs868770983, COSV100996498; called by muse, mutect2, varscan2
- KLHL12 | c.132C>T p.F44= | Silent (SNP) | VAF 63/133 reads (47%) | catalogued as rs778958066, COSV100935767; called by muse, mutect2, varscan2
- KRT34 | c.804C>T p.N268= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs550415508, COSV101222640, COSV101222646, COSV67449796; called by muse, mutect2, varscan2
- LILRA1 | c.378C>T p.T126= | Silent (SNP) | VAF 92/168 reads (55%) | catalogued as rs559793347, COSV99252081; called by muse, mutect2, varscan2
- LMCD1 | c.49C>T p.L17= | Silent (SNP) | VAF 50/200 reads (25%) | catalogued as COSV99337767; called by muse, mutect2, varscan2
- LRP1B | c.11502G>A p.Q3834= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV101259565; called by muse, mutect2, varscan2
- LRRC49 | c.1986G>A p.R662= | Silent (SNP) | VAF 65/142 reads (46%) | catalogued as COSV99537996; called by muse, mutect2, varscan2
- LTBP2 | c.2769G>A p.G923= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100000835; called by muse, mutect2, varscan2
- MAGEB6B | c.849G>A p.P283= | Silent (SNP) | VAF 176/305 reads (58%) | catalogued as rs763257224; called by muse, mutect2, varscan2
- MC3R | c.150C>T p.I50= | Silent (SNP) | VAF 83/169 reads (49%) | catalogued as COSV54765022; called by muse, mutect2, varscan2
- MEFV | c.1887G>T p.L629= | Silent (SNP) | VAF 164/408 reads (40%) | catalogued as COSV99561160; called by muse, mutect2, varscan2
- MKI67 | c.8226C>T p.F2742= | Silent (SNP) | VAF 73/125 reads (58%) | catalogued as COSV64073704; called by muse, mutect2, varscan2
- MS4A12 | c.288C>T p.I96= | Silent (SNP) | VAF 56/211 reads (27%) | catalogued as rs1285899537, COSV99189529; called by muse, mutect2, varscan2
- MUC16 | c.25509G>A p.G8503= | Silent (SNP) | VAF 89/256 reads (35%) | catalogued as rs892217387, COSV101201004; called by muse, mutect2, varscan2
- MXRA5 | c.4467G>A p.K1489= | Silent (SNP) | VAF 65/242 reads (27%) | catalogued as COSV99478691; called by muse, mutect2, varscan2
- MYH6 | c.807G>A p.L269= | Silent (SNP) | VAF 75/136 reads (55%) | catalogued as COSV100676901; called by muse, mutect2, varscan2
- MYO18B | c.3054C>T p.P1018= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV59127019; called by muse, mutect2, varscan2
- NAGA | c.1176T>C p.P392= | Silent (SNP) | VAF 68/156 reads (44%) | catalogued as COSV101124171; called by muse, mutect2, varscan2
- NGRN | c.864G>C p.L288= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV100517991; called by muse, mutect2, varscan2
- NLRP2 | c.174C>T p.I58= | Silent (SNP) | VAF 68/130 reads (52%) | catalogued as rs900214762, COSV99672564; called by muse, mutect2, varscan2
- NYNRIN | c.618C>T p.L206= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs1424353907, COSV101230669; called by muse, mutect2, varscan2
- OPRM1 | c.435G>A p.V145= | Silent (SNP) | VAF 120/166 reads (72%) | catalogued as COSV57672988; called by muse, mutect2, varscan2
- OR10AG1 | c.597G>A p.T199= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs750193037, COSV56631361; called by muse, mutect2, varscan2
- OR10G7 | c.543G>A p.P181= | Silent (SNP) | VAF 81/324 reads (25%) | catalogued as rs769432723, COSV57867848; called by muse, mutect2, varscan2
- OR1L1 | c.816C>T p.L272= (on ENST00000373686; = p.L222= on NM_001005236.3) | Silent (SNP) | VAF 101/180 reads (56%) | catalogued as COSV100542262; called by muse, mutect2, varscan2
- OR4A47 | c.690G>A p.G230= | Silent (SNP) | VAF 107/241 reads (44%) | catalogued as COSV101487089; called by muse, mutect2, varscan2
- OR4C6 | c.657C>T p.I219= | Silent (SNP) | VAF 70/122 reads (57%) | catalogued as COSV100051795, COSV58606421; called by muse, mutect2, varscan2
- OR52J3 | c.780C>T p.F260= | Silent (SNP) | VAF 96/184 reads (52%) | catalogued as rs866144843, COSV66747974; called by muse, mutect2, varscan2
- OR56A4 | c.570C>T p.I190= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV100417671; called by muse, mutect2, varscan2
- OR56B1 | c.162C>T p.I54= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV100402705; called by muse, mutect2, varscan2
- OR6S1 | c.189C>T p.F63= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as COSV100289484; called by muse, mutect2, varscan2
- OR7A5 | c.699G>A p.G233= | Silent (SNP) | VAF 67/131 reads (51%) | catalogued as COSV100457901; called by muse, mutect2, varscan2
- OR8D2 | c.816G>A p.K272= | Silent (SNP) | VAF 95/166 reads (57%) | catalogued as rs1307543913, COSV100659075; called by muse, mutect2, varscan2
- PAK3 | c.1623C>T p.S541= (on ENST00000262836 / NM_001324328.2; = p.S526= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 69/131 reads (53%) | catalogued as COSV99458119; called by muse, mutect2, varscan2
- PARP1 | c.2370C>T p.I790= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs148234314, COSV64689609; called by muse, mutect2, varscan2
- PCDH15 | c.5211G>A p.V1737= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs370313045; called by muse, varscan2
- PCDH15 | c.4983G>A p.R1661= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs867467512, COSV100902200, COSV64715566; called by muse, mutect2, varscan2
- PCDHB10 | c.171G>A p.G57= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV99504850; called by muse, mutect2, varscan2
- PCDHB11 | c.1276T>C p.L426= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as rs782595480, COSV100697139; called by muse, mutect2
- PGAP6 | c.1932C>T p.I644= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs375688501; called by muse, mutect2, varscan2
- PLXNB3 | c.3078C>T p.F1026= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100737785; called by muse, mutect2, varscan2
- PNCK | c.948C>T p.I316= (on ENST00000340888 / NM_001366975.1; = p.I399= on NM_001039582.3) | Silent (SNP) | VAF 30/45 reads (67%) | catalogued as COSV100562441; called by muse, mutect2, varscan2
- POFUT2 | c.309C>T p.P103= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100499350, COSV100499381; called by muse, mutect2, varscan2
- PRDM2 | c.1800T>C p.C600= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99342508; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1500G>A p.G500= (on ENST00000352766; = p.G421= on NM_181334.5) | Silent (SNP) | VAF 78/212 reads (37%) | catalogued as COSV100424576; called by muse, mutect2, varscan2
- PRSS16 | c.273G>A p.Q91= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs1446768437, COSV100041926; called by muse, mutect2, varscan2
- PSD | c.3015G>A p.R1005= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99193643; called by muse, mutect2, varscan2
- PTPRT | c.1143C>T p.T381= | Silent (SNP) | VAF 66/121 reads (55%) | catalogued as COSV100629660; called by muse, mutect2, varscan2
- RB1 | c.2535C>T p.F845= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as CM025392, COSV99926164; called by muse, mutect2, varscan2
- RNF213 | c.1821G>A p.T607= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs866420799, COSV60621185; called by muse, mutect2, varscan2
- SAGE1 | c.1857G>A p.R619= | Silent (SNP) | VAF 158/275 reads (57%) | catalogued as COSV100187740; called by muse, mutect2, varscan2
- SALL3 | c.1284C>G p.V428= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101610040; called by muse, mutect2
- SGSM1 | c.1263C>T p.I421= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV101241039; called by muse, mutect2, varscan2
- SIPA1L3 | c.2328C>T p.F776= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as rs61729141, COSV55912345; called by muse, mutect2, varscan2
- SLC2A4 | c.507G>A p.R169= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99142799; called by muse, mutect2, varscan2
- SLC36A3 | c.36G>A p.L12= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100077808; called by muse, mutect2, varscan2
- SLC4A8 | c.2868C>T p.T956= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV100177016, COSV100177374; called by muse, mutect2, varscan2
- SLC5A11 | c.846C>T p.S282= | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as COSV100762878; called by muse, mutect2, varscan2
- SOX30 | c.1188G>A p.K396= | Silent (SNP) | VAF 126/232 reads (54%) | catalogued as rs1028994486, COSV99398697; called by muse, mutect2, varscan2
- SPAG17 | c.5223C>T p.G1741= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100310152; called by muse, mutect2, varscan2
- SPATA31A3 | c.279G>A p.E93= | Silent (SNP) | VAF 6/27 reads (22%) | called by mutect2, varscan2
- SPTAN1 | c.4668C>T p.F1556= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100823917; called by muse, mutect2, varscan2
- STS | c.561C>T p.I187= | Silent (SNP) | VAF 103/144 reads (72%) | catalogued as rs755543529, COSV99481329; called by muse, mutect2, varscan2
- STXBP1 | c.696C>T p.I232= | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as COSV100964626; called by muse, mutect2, varscan2
- STYXL2 | c.66G>A p.V22= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1194160924, COSV99609716; called by muse, mutect2, varscan2
- SYNCRIP | c.1641C>T p.G547= | Silent (SNP) | VAF 104/129 reads (81%) | catalogued as COSV100784303; called by muse, mutect2, varscan2
- TAS2R1 | c.465C>T p.F155= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as COSV66779493; called by muse, mutect2, varscan2
- TBC1D7 | c.327C>T p.L109= | Silent (SNP) | VAF 37/276 reads (13%) | catalogued as rs1305457553, COSV100568693; called by muse, mutect2, varscan2
- TDRD5 | c.2289T>C p.T763= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs1315132790, COSV99676883; called by muse, mutect2, varscan2
- TENM4 | c.3753T>C p.I1251= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as COSV99577770; called by muse, mutect2, varscan2
- TERF1 | c.678C>T p.S226= | Silent (SNP) | VAF 87/165 reads (53%) | catalogued as COSV99401375; called by muse, mutect2, varscan2
- TESPA1 | c.927G>A p.R309= (on ENST00000316577 / NM_001098815.3; = p.R171= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs1201515525, COSV100345533; called by muse, mutect2, varscan2
- TIMM8A | c.261C>T p.S87= | Silent (SNP) | VAF 334/540 reads (62%) | catalogued as COSV100437832; called by muse, mutect2, varscan2
- TMEM74 | c.834C>T p.F278= | Silent (SNP) | VAF 72/143 reads (50%) | catalogued as COSV99865839; called by muse, mutect2, varscan2
- TMPRSS11F | c.567G>A p.R189= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as rs866314005, COSV100678739; called by muse, mutect2, varscan2
- TOX3 | c.1542C>T p.L514= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV99568005; called by muse, mutect2, varscan2
- TTN | c.873C>T p.S291= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as COSV100625438; called by muse, mutect2, varscan2
- UNC13A | c.4596C>T p.V1532= | Silent (SNP) | VAF 56/118 reads (47%) | catalogued as COSV99409266; called by muse, mutect2, varscan2
- VIL1 | c.144C>T p.I48= | Silent (SNP) | VAF 44/204 reads (22%) | catalogued as COSV50285484; called by muse, mutect2, varscan2
- XIRP2 | c.6081G>A p.K2027= (on ENST00000628543; = p.K2202= on NM_152381.6) | Silent (SNP) | VAF 60/88 reads (68%) | catalogued as COSV54724748, COSV99746291; called by muse, mutect2, varscan2
- XKRX | c.561G>A p.Q187= | Silent (SNP) | VAF 67/119 reads (56%) | catalogued as COSV100139785; called by muse, mutect2, varscan2
- XPR1 | c.1827C>T p.F609= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV100851506, COSV62559972; called by muse, mutect2, varscan2
- ZFP2 | c.918C>T p.S306= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100797112; called by muse, mutect2, varscan2
- ZMYM3 | c.597G>A p.L199= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100077950, COSV100078273; called by muse, mutect2, varscan2
- ZNF229 | c.45T>A p.S15= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV99350764; called by muse, mutect2, varscan2
- ZNF304 | c.816C>T p.I272= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV99988785; called by muse, mutect2, varscan2
- ZNF48 | c.1672C>T p.L558= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV100198206; called by muse, mutect2, varscan2
- ZNF543 | c.420C>T p.G140= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV100386896; called by muse, mutect2, varscan2
- ZNF610 | c.828A>C p.A276= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100016972; called by muse, mutect2, varscan2
- ZXDB | c.1026C>T p.G342= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs761975849, COSV100886017; called by muse, mutect2, varscan2
- ATP2B2 | c.*119C>T | 3'UTR (SNP) | VAF 38/109 reads (35%) | catalogued as COSV59502960; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1001A>G | 3'UTR (SNP) | VAF 17/50 reads (34%) | catalogued as rs1334073665, COSV100247289; called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-481-1871C>T | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs747567015, COSV101125179; called by muse, varscan2
- MIR509-3 | n.22G>A | RNA (SNP) | VAF 466/787 reads (59%) | catalogued as rs1042659295; called by muse, mutect2, varscan2
- MIR654 | n.44C>T | RNA (SNP) | VAF 5/20 reads (25%) | catalogued as rs765410808; called by muse, mutect2
- MPZL3 | c.-2G>A | 5'UTR (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99635269; called by muse, mutect2
- NRP1 | c.1759+1332G>A | Intron (SNP) | VAF 17/51 reads (33%) | catalogued as rs765757126, COSV99589441; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43304704 G>A | 3'Flank (SNP) | VAF 14/69 reads (20%) | catalogued as rs756784138; called by muse, mutect2
- RORA | c.196+51387C>T | Intron (SNP) | VAF 47/79 reads (59%) | catalogued as COSV99832992; called by muse, mutect2, varscan2
- SNX29P2 | n.766G>A | RNA (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- SPANXN1 | c.-1C>T | 5'UTR (SNP) | VAF 229/399 reads (57%) | catalogued as rs782218537, COSV65123858; called by muse, mutect2, varscan2
- SSPOP | n.4199T>G | RNA (SNP) | VAF 27/52 reads (52%) | catalogued as COSV100022876; called by muse, mutect2, varscan2
- TTN | c.34264+2961C>T | Intron (SNP) | VAF 4/9 reads (44%) | catalogued as rs1277996298, COSV100625424; called by muse, mutect2, varscan2
